Somatic mutation profile of tumor specimen 0DJM99 from CCDI case PBBXGJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 17.2 years (6,289 days).
Specimen 0DJM99: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05b869f7-3ff2-4c56-81a5-3a7ecee13e1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJM8M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a76fd5cb-c9b9-4174-b718-22b2aba943dd

The open-access MAF lists 38 somatic variants for this specimen: 21 protein-altering or splice-affecting, 9 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 9, Intron 4, 3'UTR 2, Nonsense Mutation 2, 5'UTR 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 1999/3164 reads (63%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- BICRA | c.2810dup p.P938Tfs*127 | Frame Shift Ins (INS) | VAF 56/350 reads (16%) | catalogued as rs755506199; called by mutect2, varscan2
- EIF4G1 | c.4492C>T p.R1498* (on ENST00000346169 / NM_198241.3; = p.R1303* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 404/1395 reads (29%) | catalogued as COSV59990986; called by muse, mutect2, varscan2
- EPHA8 | c.531C>A p.S177R | Missense Mutation (SNP) | VAF 201/716 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV51264203; called by muse, mutect2, varscan2
- FAM47C | c.2365G>T p.E789* | Nonsense Mutation (SNP) | VAF 935/991 reads (94%) | catalogued as COSV63724961; called by muse, mutect2, varscan2
- FBXW7 | c.1274G>T p.W425L (on ENST00000281708 / NM_001349798.2; = p.W345L on NM_018315.5) | Missense Mutation (SNP) | VAF 587/1058 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99662175; called by muse, mutect2, varscan2
- FLG | c.7424G>A p.G2475E | Missense Mutation (SNP) | VAF 155/1141 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as COSV64247311; called by muse, mutect2, varscan2
- NRBP1 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 187/1019 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.932); catalogued as rs771034587; called by muse, mutect2, varscan2
- RSBN1 | c.166G>C p.V56L | Missense Mutation (SNP) | VAF 37/1393 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as rs942331302; called by muse, mutect2
- ANKRD36B | c.374A>C p.Y125S | Missense Mutation (SNP) | VAF 417/4431 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CYP2C8 | c.26T>G p.L9R | Missense Mutation (SNP) | VAF 208/1328 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- DNAH8 | c.6812G>T p.W2271L | Missense Mutation (SNP) | VAF 250/932 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELFN1 | c.1476G>C p.E492D | Missense Mutation (SNP) | VAF 255/1763 reads (14%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- PRCP | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 407/2044 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- ROGDI | c.45+7C>T | Splice Region (SNP) | VAF 256/416 reads (62%) | called by muse, mutect2, varscan2
- SLCO1A2 | c.1957G>T p.D653Y | Missense Mutation (SNP) | VAF 297/1621 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by mutect2, varscan2
- TBC1D3F | c.80G>T p.R27L | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- USP4 | c.2170G>T p.A724S | Missense Mutation (SNP) | VAF 373/1245 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- VWA7 | c.1922G>T p.G641V | Missense Mutation (SNP) | VAF 161/638 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF726 | c.824A>T p.H275L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.38); called by mutect2, varscan2
- ZSCAN18 | c.610A>G p.T204A | Missense Mutation (SNP) | VAF 548/1712 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AZIN2 | c.1371G>A p.A457= | Silent (SNP) | VAF 222/1172 reads (19%) | catalogued as rs772472480; called by muse, mutect2, varscan2
- B3GNT9 | c.492G>A p.S164= | Silent (SNP) | VAF 208/635 reads (33%) | called by muse, mutect2, varscan2
- BAZ1A | c.3222C>T p.S1074= | Silent (SNP) | VAF 528/1674 reads (32%) | called by muse, mutect2, varscan2
- CDC42BPG | c.3432G>T p.L1144= | Silent (SNP) | VAF 161/742 reads (22%) | called by muse, mutect2, varscan2
- CDHR5 | c.1023C>T p.T341= | Silent (SNP) | VAF 224/1069 reads (21%) | catalogued as rs753840282; called by muse, varscan2
- DDRGK1 | c.585C>T p.A195= | Silent (SNP) | VAF 250/1394 reads (18%) | called by muse, mutect2, varscan2
- HOXD4 | c.90C>T p.G30= | Silent (SNP) | VAF 144/977 reads (15%) | catalogued as rs924937832, COSV60460000; called by muse, mutect2, varscan2
- HTT | c.3087G>A p.L1029= | Silent (SNP) | VAF 508/886 reads (57%) | catalogued as rs955594035; called by muse, mutect2, varscan2
- XKR3 | c.939A>C p.L313= | Silent (SNP) | VAF 649/1653 reads (39%) | called by muse, mutect2
- ACSF2 | c.1216-88A>G | Intron (SNP) | VAF 43/138 reads (31%) | called by muse, mutect2, varscan2
- ATP2A3 | c.1096-85G>T | Intron (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- DCAKD | c.*93_*98del | 3'UTR (DEL) | VAF 10/114 reads (9%) | catalogued as rs1287926316; called by pindel, varscan2
- FBXO40 | c.*18G>T | 3'UTR (SNP) | VAF 174/726 reads (24%) | catalogued as COSV100100178; called by muse, mutect2, varscan2
- GALNT6 | c.1168-38G>T | Intron (SNP) | VAF 140/580 reads (24%) | catalogued as rs748119141; called by muse, mutect2, varscan2
- H3Y1 | c.-65G>A | 5'UTR (SNP) | VAF 87/161 reads (54%) | catalogued as rs1431880504; called by muse, mutect2, varscan2
- PRELID3A | c.-34C>G | 5'UTR (SNP) | VAF 77/279 reads (28%) | catalogued as rs892699932; called by muse, mutect2, varscan2
- TRIM5 | c.744+81C>A | Intron (SNP) | VAF 57/266 reads (21%) | called by muse, mutect2, varscan2
